Somatic mutation profile of tumor specimen TCGA-SX-A7SR-01A (aliquot TCGA-SX-A7SR-01A-12D-A35Z-10) from TCGA case TCGA-SX-A7SR, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 66.4 years (24,237 days).
Specimen TCGA-SX-A7SR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2c1a2b9-ddc3-4557-9c0a-32864a2ac756.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SX-A7SR-10A (Blood Derived Normal), aliquot TCGA-SX-A7SR-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fc5bbc0-b995-42c6-bda7-de5163d1c508

The open-access MAF lists 90 somatic variants for this specimen: 74 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 15, Frame Shift Del 12, Nonsense Mutation 2, Frame Shift Ins 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB8 | c.92T>A p.V31D | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as COSV99875172; called by muse, mutect2, varscan2
- AFP | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748956575, COSV56925987; called by muse, mutect2, varscan2
- AL162417.1 | c.331G>C p.A111P | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV100923178; called by muse, mutect2, varscan2
- ANAPC5 | c.2006A>G p.K669R | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV99946566; called by muse, mutect2, varscan2
- ANKS6 | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100782407; called by muse, mutect2, varscan2
- ARHGAP6 | c.2188G>A p.E730K (on ENST00000337414 / NM_013427.3; = p.E527K on NM_013423.3) | Missense Mutation (SNP) | VAF 89/140 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as rs767991549, COSV100273659; called by muse, mutect2, varscan2
- ATL1 | c.855A>T p.K285N | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV100613351; called by muse, mutect2, varscan2
- ATP1A4 | c.2311G>C p.G771R | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100927658; called by muse, mutect2, varscan2
- CCDC121 | c.559T>C p.F187L | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV99270601; called by muse, mutect2, varscan2
- CDHR2 | c.3784G>A p.E1262K | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV56143811; called by muse, mutect2, varscan2
- CHD9 | c.4432C>G p.P1478A | Missense Mutation (SNP) | VAF 70/139 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV99529877; called by muse, mutect2, varscan2
- CIART | c.850T>G p.L284V | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV99290456; called by muse, mutect2, varscan2
- CNTROB | c.1915C>A p.L639I | Missense Mutation (SNP) | VAF 81/146 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.445); catalogued as COSV100972803; called by muse, mutect2, varscan2
- CRLF3 | c.713A>T p.H238L | Missense Mutation (SNP) | VAF 71/125 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV100158582; called by muse, mutect2, varscan2
- CTTNBP2 | c.2638G>A p.E880K | Missense Mutation (SNP) | VAF 71/155 reads (46%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs1015913590, COSV50443813; called by muse, mutect2, varscan2
- CUBN | c.580A>G p.M194V | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs968919641, COSV100910702; called by muse, mutect2, varscan2
- DCTN4 | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.157); catalogued as COSV101437596; called by muse, mutect2, varscan2
- DPP7 | c.434T>C p.L145P | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100857449; called by muse, mutect2, varscan2
- DRC7 | c.586A>T p.M196L | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100395947; called by muse, mutect2, varscan2
- EDIL3 | c.671T>G p.M224R | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99679610; called by muse, mutect2, varscan2
- EFCAB5 | c.3941T>C p.I1314T | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as rs770481406, COSV100300929; called by muse, mutect2, varscan2
- GNPNAT1 | c.263T>A p.V88D | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99369731; called by muse, mutect2, varscan2
- GREB1 | c.361G>C p.G121R | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99303994; called by muse, mutect2, varscan2
- HELZ2 | c.2501C>G p.S834C (on ENST00000467148 / NM_001037335.2; = p.S265C on NM_033405.3) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100915380, COSV100915734; called by muse, mutect2, varscan2
- HMGCS1 | c.1055C>G p.S352C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.038); catalogued as COSV100285105; called by muse, mutect2, varscan2
- KIAA1109 | c.5942A>C p.D1981A | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99191258; called by muse, mutect2, varscan2
- KLK7 | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs758785488, COSV100304521; called by muse, mutect2, varscan2
- KRT5 | c.332C>A p.A111D | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV99358329; called by muse, mutect2
- LAMB1 | c.4342G>A p.D1448N | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.468); catalogued as COSV55970784, COSV99741868; called by muse, mutect2, varscan2
- LTBP4 | c.444G>C p.K148N (on ENST00000308370 / NM_001042544.1; = p.K111N on NM_003573.2) | Missense Mutation (SNP) | VAF 71/222 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV99199780; called by muse, mutect2, varscan2
- MACF1 | c.2215C>G p.L739V | Missense Mutation (SNP) | VAF 30/84 reads (36%) | catalogued as rs1220632370, COSV58411324; called by muse, mutect2, varscan2
- MKNK2 | c.896G>A p.C299Y | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1267536821, COSV99170459; called by muse, mutect2, varscan2
- MMEL1 | c.62G>T p.R21L | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99984616; called by muse, varscan2
- MORC2 | c.1865T>C p.I622T (on ENST00000397641 / NM_001303256.3; = p.I560T on NM_014941.3) | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.395); catalogued as COSV99310562; called by muse, mutect2, varscan2
- MTA1 | c.1331A>T p.N444I | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as COSV100495528; called by muse, mutect2, varscan2
- MX2 | c.1262T>C p.F421S | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100416250; called by muse, mutect2, varscan2
- MYCBP2 | c.481A>C p.I161L (on ENST00000357337; = p.I199L on NM_015057.5) | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.558); catalogued as COSV100632326, COSV62012897; called by muse, mutect2, varscan2
- NEK3 | c.40T>C p.S14P | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99317836; called by muse, mutect2
- NNAT | c.156G>T p.Q52H (on ENST00000649309 / NM_001322802.2; = p.R54M on NM_005386.4) | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.991); catalogued as COSV50351606; called by muse, mutect2, varscan2
- NT5C | c.322T>A p.C108S | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV99822766; called by muse, mutect2, varscan2
- NUGGC | c.1000C>A p.L334M | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV100429882; called by muse, mutect2, varscan2
- PAWR | c.451A>T p.I151F | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100174457; called by muse, mutect2, varscan2
- PDE3A | c.2773A>T p.N925Y | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100762933; called by muse, mutect2, varscan2
- PIK3C2A | c.1973T>C p.L658P | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99791374; called by muse, mutect2, varscan2
- PLPPR3 | c.814G>A p.G272S (on ENST00000520876 / NM_001270366.2; = p.G300S on NM_024888.2) | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); catalogued as COSV100609217; called by muse, mutect2, varscan2
- PPP6C | c.461T>A p.L154* | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | catalogued as COSV101001274; called by muse, mutect2, varscan2
- PRDM2 | c.415T>A p.W139R | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV99342901; called by muse, mutect2, varscan2
- PTPN21 | c.2479A>T p.K827* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as COSV100162628; called by muse, mutect2, varscan2
- RASGRF1 | c.856G>A p.V286I | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.592); catalogued as rs766133238, COSV101369783; called by muse, mutect2, varscan2
- RBMS2 | c.581_582insT p.F195Lfs*2 | Frame Shift Ins (INS) | VAF 49/114 reads (43%) | catalogued as COSV100008733; called by mutect2, pindel, varscan2
- RTL9 | c.3484T>C p.C1162R | Missense Mutation (SNP) | VAF 114/150 reads (76%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.667); catalogued as rs778189661, COSV101511817; called by muse, mutect2, varscan2
- SCRN2 | c.602T>C p.I201T | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as COSV99274341, COSV99274376; called by muse, mutect2, varscan2
- SH2D3C | c.2288C>T p.P763L (on ENST00000314830 / NM_170600.3; = p.P606L on NM_005489.4) | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.93); PolyPhen benign (0.012); catalogued as COSV100137722; called by muse, mutect2, varscan2
- SLC35A4 | c.584A>T p.Y195F | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100021560; called by muse, mutect2, varscan2
- SLC38A11 | c.49T>A p.S17T | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV100367087; called by muse, varscan2
- SLC38A8 | c.-2C>T | Splice Region (SNP) | VAF 10/57 reads (18%) | catalogued as rs376267915; called by muse, mutect2
- SLC8A3 | c.1319C>A p.A440D | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100776415, COSV63523522; called by muse, mutect2
- ST6GALNAC5 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 33/97 reads (34%) | PolyPhen probably damaging (0.976); catalogued as COSV100603133; called by muse, mutect2, varscan2
- TBC1D10A | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV99305032; called by muse, mutect2, varscan2
- TEX9 | c.769_770del p.F257Rfs*8 | Frame Shift Del (DEL) | VAF 142/462 reads (31%) | catalogued as rs780583172; called by mutect2, pindel, varscan2
- TUBGCP2 | c.2402C>T p.A801V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99428415; called by muse, mutect2, varscan2
- TUBGCP2 | c.2401G>A p.A801T | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs767506396, COSV99428416; called by muse, mutect2, varscan2
- CERS3 | c.1052dup p.E352Gfs*21 | Frame Shift Ins (INS) | VAF 19/66 reads (29%) | called by mutect2, pindel, varscan2
- CNST | c.2030del p.F677Sfs*42 | Frame Shift Del (DEL) | VAF 27/93 reads (29%) | called by mutect2, pindel, varscan2
- CNTF | c.173_179del p.V58Afs*8 | Frame Shift Del (DEL) | VAF 37/108 reads (34%) | called by mutect2, pindel, varscan2
- LRRK1 | c.1085del p.N362Ifs*3 | Frame Shift Del (DEL) | VAF 61/219 reads (28%) | called by mutect2, pindel, varscan2
- MTOR | c.6902_6915delinsGGCCAAGCT p.K2301Rfs*4 | Frame Shift Del (DEL) | VAF 13/31 reads (42%) | called by pindel, varscan2*
- NET1 | c.479del p.L160Rfs*5 (on ENST00000355029 / NM_001047160.3; = p.L106Rfs*5 on NM_005863.5) | Frame Shift Del (DEL) | VAF 29/107 reads (27%) | called by mutect2, pindel, varscan2
- SLC41A3 | c.1503del p.L501Ffs*2 | Frame Shift Del (DEL) | VAF 67/231 reads (29%) | called by mutect2, pindel, varscan2
- SMC6 | c.812del p.L271* | Frame Shift Del (DEL) | VAF 103/381 reads (27%) | called by mutect2, pindel, varscan2
- SPIDR | c.1982_1994del p.K661Ifs*10 | Frame Shift Del (DEL) | VAF 15/79 reads (19%) | called by mutect2, pindel, varscan2
- TEP1 | c.7278del p.F2426Lfs*14 | Frame Shift Del (DEL) | VAF 31/117 reads (26%) | called by mutect2, pindel, varscan2
- TF | c.2084del p.F695Sfs*15 | Frame Shift Del (DEL) | VAF 22/85 reads (26%) | called by mutect2, pindel, varscan2
- XDH | c.1246del p.E416Sfs*19 | Frame Shift Del (DEL) | VAF 30/76 reads (39%) | called by mutect2, pindel, varscan2
- ARHGEF11 | c.4416T>G p.A1472= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as COSV100169070; called by muse, mutect2, varscan2
- CLSTN1 | c.312C>A p.S104= (on ENST00000377298 / NM_001009566.3; = p.S94= on NM_014944.4) | Silent (SNP) | VAF 43/116 reads (37%) | catalogued as COSV100790808; called by muse, mutect2, varscan2
- EPS8L1 | c.234G>A p.L78= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV99137317; called by muse, mutect2, varscan2
- FJX1 | c.1212C>G p.A404= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as COSV100502800; called by muse, mutect2, varscan2
- GOLPH3L | c.558T>C p.T186= | Silent (SNP) | VAF 55/163 reads (34%) | catalogued as COSV99654084; called by muse, mutect2, varscan2
- GPRASP1 | c.834T>C p.D278= | Silent (SNP) | VAF 41/59 reads (69%) | catalogued as COSV100851101; called by muse, mutect2, varscan2
- HERC2 | c.7188C>T p.A2396= | Silent (SNP) | VAF 47/154 reads (31%) | catalogued as COSV99877457; called by muse, mutect2, varscan2
- LRP1 | c.11304G>A p.G3768= | Silent (SNP) | VAF 44/146 reads (30%) | catalogued as COSV99677672; called by muse, mutect2, varscan2
- MAGI1 | c.3345A>T p.A1115= (on ENST00000402939 / NM_001033057.2; = p.A1144= on NM_004742.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 66/161 reads (41%) | catalogued as COSV100443403, COSV58346196; called by muse, mutect2, varscan2
- METAP2 | c.1425A>T p.G475= | Silent (SNP) | VAF 35/122 reads (29%) | catalogued as COSV99312120; called by muse, mutect2, varscan2
- PPARD | c.147C>A p.S49= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV100283195, COSV100283414; called by muse, mutect2, varscan2
- SDR9C7 | c.540G>A p.E180= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as COSV99524722; called by muse, mutect2, varscan2
- SGSM2 | c.1317C>A p.G439= (on ENST00000426855 / NM_001098509.2; = p.G484= on NM_014853.3) | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV99280655; called by muse, mutect2, varscan2
- UCP3 | c.552C>A p.P184= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV100013103; called by muse, mutect2, varscan2
- ULK2 | c.942G>A p.Q314= | Silent (SNP) | VAF 71/157 reads (45%) | catalogued as COSV100861039; called by muse, mutect2, varscan2
- SPATA8 | n.864del | RNA (DEL) | VAF 15/47 reads (32%) | called by mutect2, pindel, varscan2
